Somatic mutation profile of tumor specimen TCGA-B0-5710-01A (aliquot TCGA-B0-5710-01A-11D-1669-08) from TCGA case TCGA-B0-5710, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.0 years (21,168 days).
Specimen TCGA-B0-5710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6e40f85-8fc9-4f82-a43d-49d6fd8935ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5710-11A (Solid Tissue Normal), aliquot TCGA-B0-5710-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae54017b-e22f-4638-bb7b-69e7406ca93b

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 24, Silent 10, Frame Shift Del 3, In Frame Del 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP2 | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58752074; called by muse, mutect2, varscan2
- ADAMTS14 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV64602273; called by muse, mutect2
- ANKRD22 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 116/360 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV64236530; called by muse, mutect2, varscan2
- BLM | c.1603A>C p.K535Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV61924170; called by muse, mutect2, varscan2
- CD96 | c.1306T>A p.S436T (on ENST00000283285 / NM_198196.3; = p.S420T on NM_005816.5) | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV51916547; called by muse, mutect2, varscan2
- DNAH10 | c.9434C>A p.A3145D (on ENST00000409039; = p.A3084D on NM_207437.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV68994167; called by muse, mutect2, varscan2
- GRN | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV50006809; called by muse, mutect2, varscan2
- KAT6A | c.1988T>C p.I663T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55906255; called by muse, mutect2, varscan2
- L3MBTL4 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs1477345339, COSV53123137; called by muse, mutect2
- LATS1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs747900347, COSV53591286; called by muse, mutect2, varscan2
- MYO3A | c.787T>G p.F263V | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56331569; called by muse, mutect2, varscan2
- MYRF | c.1459A>G p.N487D (on ENST00000278836 / NM_001127392.3; = p.N478D on NM_013279.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53888786; called by muse, mutect2
- NCAPD2 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV59699501; called by muse, mutect2, varscan2
- NEXMIF | c.2357C>A p.T786N | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV50032282; called by muse, mutect2, varscan2
- NF1 | c.8233G>T p.G2745* (on ENST00000358273 / NM_001042492.3; = p.G2724* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 56/219 reads (26%) | catalogued as COSV62196669, COSV62204293; called by muse, mutect2, varscan2
- NUP210L | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 95/367 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV55148027; called by muse, mutect2, varscan2
- PBRM1 | c.2242del p.D748Mfs*27 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as COSV56277344; called by mutect2, pindel, varscan2
- PPP4R3A | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV61504775; called by muse, mutect2, varscan2
- PRUNE2 | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65027777; called by muse, mutect2, varscan2
- RPS6KA1 | c.1615A>T p.S539C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65176451; called by muse, mutect2, varscan2
- SERINC1 | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV60102075; called by muse, mutect2, varscan2
- SF3B3 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56787738, COSV56790058; called by muse, mutect2, varscan2
- SLC22A25 | c.1153T>C p.F385L | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV60596094; called by muse, mutect2
- SLC5A7 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV50891933; called by muse, mutect2, varscan2
- SMURF2 | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as COSV52315515; called by muse, mutect2, varscan2
- STXBP2 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as rs1030575812, COSV55403398; called by muse, mutect2, varscan2
- MRM1 | c.463del p.D155Ifs*33 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- NDUFS1 | c.776_778del p.S259del | In Frame Del (DEL) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- SLCO1B3 | c.141del p.M48* | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- UBC | c.266_268del p.I89del | In Frame Del (DEL) | VAF 43/249 reads (17%) | called by mutect2, pindel, varscan2
- YIPF4 | c.483+2dup p.X161_splice | Splice Site (INS) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- APLP1 | c.642G>A p.G214= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1387645914, COSV55703512; called by muse, mutect2, varscan2
- BAZ1B | c.1581A>G p.E527= | Silent (SNP) | VAF 14/240 reads (6%) | catalogued as COSV59991318; called by muse, mutect2
- CLDN4 | c.135C>T p.T45= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1554634051, COSV52895892; called by muse, mutect2, varscan2
- DAGLA | c.3057C>T p.I1019= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV57196228; called by muse, mutect2, varscan2
- DIO1 | c.441A>G p.A147= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV59517993; called by muse, mutect2, varscan2
- RAB24 | c.528T>C p.A176= | Silent (SNP) | VAF 33/176 reads (19%) | catalogued as COSV57463317; called by muse, mutect2, varscan2
- RABGGTB | c.321G>A p.L107= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as rs1173451585, COSV60637660; called by muse, varscan2
- TEP1 | c.4404C>T p.C1468= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1294704364, COSV52992839; called by muse, mutect2
- TTN | c.11457C>T p.G3819= (on ENST00000591111; = p.G3773= on NM_003319.4) | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as COSV60074864; called by muse, mutect2, varscan2
- UBQLN3 | c.1932C>T p.D644= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs560557342, COSV61164265; called by muse, mutect2, varscan2
